Somatic mutation profile of tumor specimen 0DJ6KJ from CCDI case PBBVBA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 14.7 years (5,362 days).
Specimen 0DJ6KJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17e99c07-3ace-4c6c-a0f0-b29742d03eca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6JZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8d4e754-2813-41d9-aa69-82f33119fbf5

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 269/932 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, varscan2
- CYP4F3 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 291/1022 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV55406706; called by muse, varscan2
- FAM43A | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 189/633 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1190189774; called by muse, varscan2
- NXPE1 | c.1606G>T p.G536* (on ENST00000424269; = p.G394* on NM_152315.5) | Nonsense Mutation (SNP) | VAF 314/1011 reads (31%) | called by muse, varscan2
- TP53AIP1 | chr11:128935038 T>C | 3'Flank (SNP) | VAF 149/568 reads (26%) | called by muse, varscan2
